Somatic mutation profile of tumor specimen MBCProject_5799_T1_WES (aliquot MBCProject_5799_T1_WES_1) from CMI case MBCProject_5799, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.9 years (18,941 days).
Specimen MBCProject_5799_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dd7c6b6-2a74-4124-89cb-c0e41507bc97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5799_SALIVA (Saliva), aliquot MBCProject_5799_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a99ef616-b2bf-426c-a334-99363b2226f8

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.2121A>C p.E707D | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99444455; called by muse, mutect2, varscan2
- AKAP9 | c.5723_5726del p.T1908Sfs*2 (on ENST00000359028; = p.T1876Sfs*2 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/479 reads (14%) | catalogued as rs755378911; called by pindel, varscan2
- ANKRD12 | c.3359_3363del p.I1120Rfs*2 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | catalogued as rs767961431; called by pindel, varscan2
- CARD11 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67803459; called by muse, mutect2, varscan2
- EHBP1L1 | c.4388G>A p.R1463Q | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58572353; called by muse, mutect2, varscan2
- IRX2 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs745365936; called by muse, mutect2, varscan2
- SETD1A | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs1400755934, COSV52684938; called by muse, mutect2, varscan2
- SETD2 | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 34/155 reads (22%) | catalogued as COSV57435667; called by muse, mutect2, varscan2
- VIM | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 127/569 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs866598895; called by muse, mutect2, varscan2
- ACACB | c.4240-1G>A p.X1414_splice | Splice Site (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- ANKRD36C | c.1490A>C p.K497T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.096); called by mutect2, varscan2
- CRB1 | c.4065G>C p.L1355F | Missense Mutation (SNP) | VAF 141/571 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GTF2H1 | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IQGAP2 | c.1779A>T p.R593S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDR | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 78/426 reads (18%) | called by muse, mutect2, varscan2
- KNL1 | c.4949A>G p.K1650R (on ENST00000346991 / NM_170589.5; = p.K1624R on NM_144508.5) | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RILP | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- THUMPD3 | c.989C>G p.T330S | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZNF230 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF644 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH1 | c.639G>A p.P213= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as rs754271106, COSV56253723; called by muse, mutect2, varscan2
- ITIH5 | c.309A>G p.G103= | Silent (SNP) | VAF 88/379 reads (23%) | called by muse, mutect2, varscan2
- OR6P1 | c.195T>C p.H65= | Silent (SNP) | VAF 56/282 reads (20%) | called by muse, varscan2
- PEX6 | c.519C>T p.S173= | Silent (SNP) | VAF 58/223 reads (26%) | called by muse, mutect2, varscan2
- POGLUT2 | c.1329A>C p.A443= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
